Somatic mutation profile of tumor specimen 0DOJXR from CCDI case PBCBKV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.2 years (3,358 days).
Specimen 0DOJXR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84a097f1-04c3-471c-a57e-951b9a4aa8bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOJUR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0aaddd61-525d-498a-a5ad-ac6340d9c0cd

The open-access MAF lists 17 somatic variants for this specimen: 9 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 6, 3'UTR 1, Nonsense Mutation 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYCN | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 70/259 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519919, COSV55257406, COSV55259752; ClinVar: likely pathogenic; called by muse, varscan2
- PRKAB1 | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 55/451 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.536); catalogued as rs781670874; called by muse, mutect2, varscan2
- SRPRA | c.1817T>C p.I606T | Missense Mutation (SNP) | VAF 80/358 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.145); catalogued as COSV59743614; called by muse, mutect2, varscan2
- TRPC6 | c.2336A>G p.K779R | Missense Mutation (SNP) | VAF 63/962 reads (7%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs1446204447, COSV100723764; called by muse, mutect2
- ZMYM3 | c.143dup p.G49Wfs*13 | Frame Shift Ins (INS) | VAF 116/130 reads (89%) | catalogued as rs757506048; called by mutect2, varscan2
- DNAH3 | c.11762G>A p.G3921D | Missense Mutation (SNP) | VAF 73/412 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCTD7 | c.737G>A p.W246* (on ENST00000275532; = p.V259= on NM_153033.5) | Nonsense Mutation (SNP) | VAF 52/387 reads (13%) | called by muse, mutect2, varscan2
- LARGE2 | c.1651C>A p.L551M | Missense Mutation (SNP) | VAF 45/412 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- SPINK5 | c.2081G>T p.G694V | Missense Mutation (SNP) | VAF 120/815 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- CCDC14 | c.1419A>T p.P473= (on ENST00000488653; = p.P425= on NM_022757.5) | Silent (SNP) | VAF 120/923 reads (13%) | catalogued as rs140280602; called by muse, mutect2, varscan2
- MYH11 | c.2469C>T p.C823= | Silent (SNP) | VAF 54/399 reads (14%) | catalogued as rs749478973, COSV100259591, COSV55562270; called by muse, mutect2, varscan2
- NUMBL | c.630C>T p.A210= | Silent (SNP) | VAF 42/337 reads (12%) | catalogued as rs747724511; called by muse, mutect2, varscan2
- PLAU | c.561C>T p.I187= | Silent (SNP) | VAF 188/441 reads (43%) | catalogued as rs559848125, COSV65641595; called by muse, mutect2, varscan2
- RBSN | c.1932T>C p.P644= | Silent (SNP) | VAF 233/549 reads (42%) | catalogued as rs1460399387; called by muse, mutect2, varscan2
- TTC12 | c.1497C>T p.L499= | Silent (SNP) | VAF 76/388 reads (20%) | called by muse, mutect2, varscan2
- TBC1D8B | c.1838-668A>C | Intron (SNP) | VAF 13/424 reads (3%) | called by muse, mutect2
- YIPF7 | c.*17C>T | 3'UTR (SNP) | VAF 197/436 reads (45%) | catalogued as rs1455445660; called by muse, mutect2, varscan2
